Gene-level copy-number profile of tumor specimen TCGA-DX-A48R-01A from TCGA case TCGA-DX-A48R, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 41.4 years (15,107 days).
Specimen TCGA-DX-A48R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.084383c9-5045-4b23-bc79-962685f7da85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A48R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/61150010-6446-4637-ad8f-93d1e8059850

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 60; copy number 2: 16,357; copy number 3: 4,972; copy number 4: 35,017; copy number 5: 438; copy number 6: 1,886; copy number 7: 71; copy number 9: 5; copy number 10: 79; copy number 11: 444; copy number 12: 7; copy number 15: 65; copy number 16: 227; copy number 22: 80; copy number 32: 57; copy number 33: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A48R-01A-11D-A306-01): tumor purity 0.97, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:159,028,175–159,233,377, 3 genes (within-gene range 0–2): VIPR2, AC007269.1, PIP5K1P2.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr17:22,331,597–22,706,703, 22 genes: AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 983 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–197,341, 4 genes, copy number 9: LINC01986, AC066595.1, CHL1-AS2, AC066595.2.
- chr3:282,689–282,792, 1 gene, copy number 9: RNU6-1194P.
- chr3:1,905,651–2,089,211, 3 genes, copy number 10: RPL21P17, AC018814.1, RN7SKP144.
- chr3:2,110,409–2,144,241, 2 genes, copy number 10: CNTN4-AS2, AC087427.1.
- chr17:7,686,071–21,641,536, 529 genes, copy number 10–33 (broad region; genes not listed).
- chr19:28,435,388–28,727,680, 1 gene, copy number 11 (within-gene range 7–11): AC005394.2.
- chr19:28,491,864–28,632,728, 1 gene, copy number 11 (within-gene range 7–11): AC005394.1.
- chr19:28,602,379–40,122,168, 442 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
